Somatic mutation profile of tumor specimen TCGA-CE-A485-01A (aliquot TCGA-CE-A485-01A-11D-A23U-08) from TCGA case TCGA-CE-A485, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 32.8 years (11,997 days).
Specimen TCGA-CE-A485-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7a22557-1c10-4476-80c7-5f78ff6619cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CE-A485-10A (Blood Derived Normal), aliquot TCGA-CE-A485-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccf630aa-5863-4d31-ab9a-137b8f348d24

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GYS2 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as COSV53929993; called by muse, mutect2
- RASGRF2 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747204480, COSV54141313; called by muse, mutect2, varscan2
- ZFPM2 | c.1046A>G p.N349S | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1290587796, COSV65876448; called by muse, mutect2, varscan2
